Gene-level copy-number profile of tumor specimen TCGA-EK-A2R7-01A from TCGA case TCGA-EK-A2R7, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 45.1 years (16,487 days).
Specimen TCGA-EK-A2R7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.8e132c07-321d-4e79-bfc6-165c9e3a0062.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EK-A2R7-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/42eb3984-fa3a-42df-8ab6-fefb42bd3403

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 4,113; copy number 3: 3,106; copy number 4: 40,314; copy number 5: 786; copy number 6: 7,634; copy number 8: 1,798; copy number 9: 370; copy number 10: 5; copy number 11: 1,686.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EK-A2R7-01A-11D-A18H-01): tumor purity 0.69, ploidy 2.17, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,061 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:17,684,584–45,895,970, 370 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr14:33,924,227–34,486,447, 5 genes, copy number 10: EGLN3, EGLN3-AS1, AL356806.1, SPTSSA, RPL23AP71.
- chr19:27,638,483–58,605,223, 1,686 genes, copy number 11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
